Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88M, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88M-01A (Primary Tumor).

[page 1 of 4]
Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology

Final Results

Surgical Pathology
CASE NUMBER:
DIAGNOSIS:

Final

1. Prostate, resection:
- Adenocarcinoma, gleason score 7 (3+4) involving 35% of the Left and 15% of the Right Lobes. Perineural invasion present.
- No seminal vesicle involvement identified
- Inked margins are free of tumor
- See Note
2. Lymph node, left obturator, resection:
- Lymph nodes (0/4). No tumor seen
3. Lymph node, right obturator, resection:
- Lymph nodes (0/7)
- No tumor seen
4. Lymph node, fat over anterior prostate, resection:
- Lymph node (0/1). No tumor seen
5. Bladder, neck, resection:
- Bladder and fibromuscular tissue with benign prostatic glands
- Lymph node (0/1). No tumor seen
6. Bladder, final neck margin, resection: Fibrin and blood

NOTE: One area suspicious for extra-capsular invasion is identified but definitive diagnosis cannot be done due to tissue procurement.

PROSTATE GLAND: Radical Prostatectomy

Procedure
Radical prostatectomy

Prostate Size
Weight: 34.9 g
Size: 4.5 x 4.5 x 3.0 cm

Lymph Node Sampling
Pelvic lymph node dissection

Histologic Type
Adenocarcinoma

Histologic Grade
Gleason Pattern

Primary Pattern
Grade 3

Secondary Pattern
Grade 4

GLEF ICD-O-3
Adenocarcinoma, acinar
path 8140/3
Adenocarcinoma NOS
Site Prostate NOS 8140/3
C61.9
8140/3

[page 2 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol	Admit Protocol:	Age:
		Location:

Surgical Pathology

Final Results

Total Gleason Score: 7

Tumor Quantitation

Proportion (percentage) of prostate involved by tumor:

35% of Left Lobe

15% of Right Lobe

Extraprostatic Extension

Indeterminate

Seminal Vesicle Invasion

Not identified

Margins

Margins uninvolved by invasive carcinoma

Treatment Effect on Carcinoma

Not identified

Lymph-Vascular Invasion

Not identified

Perineural Invasion

Present

Pathologic Staging (pTNM)

Primary Tumor (pT)

pT2c: Bilateral disease.

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined

Specify: 13

Number of Lymph Nodes Involved

Specify: 0

Distant Metastasis (pM)

Not applicable

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: M with prostate

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 3 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology**Final Results**

cancer Specimen Taken For
Protocol: Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: no obvious extracapsular extension
Post-Operative
Diagnosis: prostate cancer Pre-Operative Diagnosis: prostate cancer

SPECIMENS SUBMITTED: 1. PROSTATE
2. OBTURATOR LYMPH NODE(S), Left
3. OBTURATOR LYMPH NODE(S), Right
4. LYMPH NODES, Fat over anterior prostate
5. BLADDER, URINARY, Neck
6. BLADDER, URINARY, Final margin

GROSS DESCRIPTION: Received are 6 formalin-filled containers labeled with the patient's name, medical record number and further specified as follows:

1. "Prostate" consists of a prostatectomy specimen weighing 34.9 grams with the following measurements: Left to right 4.5 cm, anterior to posterior 3.0 cm, apex to base 4.5 cm, left seminal vesicles 3.2 x 1.2 cm, left vas deferens 3.2 x 0.6 cm, right seminal vesicles 2.8 x 1.5 cm, right vas deferens 3.2 x 0.8 cm. The prostate is inked as follows: Urethra in yellow, anterior 1/3 in black, right posterior 2/3 in blue, and left posterior 2/3 in red. Gross photographs are taken. One cut is made revealing a tan nodular cut surface and a hard nodule 0.5 cm in greatest dimensions is identified on the left side. Approximately 0.5 x 0.5 x 0.1 cm of tissue from the left anterior region of the tumor is procured, along with 0.7 x 0.4 x 0.1 cm, 0.9 x 0.8 x 0.2 cm, 0.7 x 0.5 x 0.1 cm, 0.4 x 0.3 x 0.1 cm, 0.6 x 0.4 x 0.1 cm pieces of tissue from the right anterior region considered normal that is procured. Of note, there are 3 separate regions from the left anterior region in the tumor that were procured approximately all the same size. The procedure was performed by _____ with the _____

Received in Pathology is the above-mentioned specimen in a formalin-filled container. The seminal vesicles and vas deferens are excised off the main prostate specimen. The prostate mold has been made and the entire prostate is fitted into the designed plastic mold and serially sectioned into 7 sections. The section from the apex of the prostate is placed into a cassette labeled _____ and the base of the prostate is placed into _____. The seminal vesicles and vas deferens are serially sectioned. The red-colored left vas deferens and seminal vesicle is placed entirely into white cassettes labeled H-1K. The blue inked right seminal vesicle and vas deferens are serially sectioned and placed into white cassettes labeled N, 10 and 1P.

2. "Left obturator lymph node" consists of a 3 x 1 x 1 cm matted lymph

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By: _____

Do not file in Medical Record

[page 4 of 4]
Gender: Male

Birth Date:

Admit Protocol:

Admit Protocol:

Admit Protocol:

Age:

Location:

Surgical PathologyFinal Results

node soft tissue specimen. There appears to be 2 large lymph nodes with the first lymph node measuring 2 x 1 x 0.5 and placed entirely into the cassette labeled . A second lymph node measuring 1 x 0.5 x 0.5-cm is placed entirely into cassette labeled and multiple smaller nodules connected with adipose tissue are placed into cassette labeled . Of note, the entire specimen has been placed into all 3 cassettes.

3. "Right obturator lymph node pocket" consists of a 3.5 x 1.5 x 1 cm matted nodal specimen. After separation, there appears to be 1 large dominant node measuring 2 x 1.5 x 0.5 that is placed entirely into cassette labeled . There are 4 smaller nodes measuring 0.3 to 0.5 cm in size that are placed into white cassette labeler 3B. Remaining subcutaneous tissue is placed into white cassettes labeled and 3D. Of note, the entire specimen has been placed into these 4 cassettes.

4. "Fat and lymph node over anterior prostate" consists of an aggregate of 4 x 2.5 x 1 cm of adipose-like tissue that is divided and placed entirely into white cassettes labeled -4D.

5. "Bladder neck" consists of 3 white-tan soft tissue fragments measuring 1 cm in size for 2 fragments and 1.5 cm in size for the third fragment. The 2.1-cm in diameter tissue fragments are placed into a white cassette labeled and the 1.5-cm irregular tan soft tissue fragment is placed into 5B.

6. "Final bladder neck margin" consists of a tiny 0.3-cm soft tissue fragment that is placed into a biopsv bag and submitted in total into a white cassette labeler

Gross Description dictated by
Description dictated by

Additional Gross

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Source: NCI Genomic Data Commons file a27a7aa4-ac1b-4f12-a4dc-3c6cc0c3acca (TCGA-VN-A88M.787071AD-ED3D-46CA-8982-2087EE6AC0EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).